Somatic mutation profile of tumor specimen MP2PRT-PAUGMH-TMP1-A (aliquot MP2PRT-PAUGMH-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUGMH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 2.0 years (725 days).
Specimen MP2PRT-PAUGMH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 411453bd-4116-4ac0-a858-3d275494dc73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUGMH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUGMH-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a85331d-210b-424b-9518-40c087556e06

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRBA | c.6226G>A p.G2076S | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200210443, COSV100841673; called by muse, mutect2
- MOCS1 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 37/454 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs754387991, COSV57933847; called by muse, mutect2
- HTR1B | c.178A>T p.T60S | Missense Mutation (SNP) | VAF 156/495 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714683 CTCTC>GGGG | Missense Mutation (DEL) | VAF 18/70 reads (26%) | called by pindel, varscan2*
- KRTAP5-2 | c.458G>T p.C153F | Missense Mutation (SNP) | VAF 189/654 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ZMYM2 | c.1153G>T p.G385* | Nonsense Mutation (SNP) | VAF 12/322 reads (4%) | called by muse, mutect2
- ATP7B | c.4338C>T p.D1446= | Silent (SNP) | VAF 117/372 reads (31%) | catalogued as rs760661082; called by muse, mutect2, varscan2
- CACNA1A | c.7455G>A p.A2485= | Silent (SNP) | VAF 36/710 reads (5%) | catalogued as rs1158240590; called by muse, mutect2
